Somatic mutation profile of tumor specimen TCGA-BR-6456-01A (aliquot TCGA-BR-6456-01A-11D-1800-08) from TCGA case TCGA-BR-6456, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.7 years (27,288 days).
Specimen TCGA-BR-6456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03374277-73b8-49b6-ba3f-5d0f9bcca2f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6456-10A (Blood Derived Normal), aliquot TCGA-BR-6456-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab94e350-2317-4c24-a68b-ec3d953d411b

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Frame Shift Del 2, Translation Start Site 1, Nonsense Mutation 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4100G>T p.G1367V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV61263080; called by muse, mutect2, varscan2
- ADGRV1 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67985175; called by muse, mutect2, varscan2
- ALOX12 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.216); catalogued as COSV52349686; called by muse, mutect2, varscan2
- ARHGAP31 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747656695, COSV51792969; called by muse, mutect2, varscan2
- CKAP5 | c.2631G>T p.R877S | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56367776; called by muse, mutect2, varscan2
- COL4A1 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65425675; called by muse, mutect2, varscan2
- DBX2 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV60337695; called by muse, mutect2
- DYNC2H1 | c.12244A>T p.N4082Y | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV62094219; called by muse, mutect2, varscan2
- GABRQ | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64781991; called by muse, mutect2, varscan2
- GPRIN1 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56138706, COSV56139429; called by muse, mutect2, varscan2
- GTF2I | c.2585T>C p.V862A (on ENST00000573035 / NM_032999.4; = p.V821A on NM_001518.5) | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.923); catalogued as rs1554410253, COSV100259346, COSV60401808; called by muse, mutect2, varscan2
- LRRK2 | c.2041T>C p.S681P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.34); catalogued as rs989859148, COSV54153301; called by muse, mutect2, varscan2
- LY9 | c.590A>G p.H197R | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV54434028; called by muse, mutect2, varscan2
- MED8 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51940977; called by muse, mutect2
- MMP8 | c.1305T>A p.H435Q | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV52632549; called by muse, mutect2, varscan2
- MTPAP | c.864A>C p.L288F | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV53932976; called by muse, mutect2, varscan2
- MUC16 | c.29687C>G p.A9896G | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.263); catalogued as COSV67465871; called by muse, mutect2
- NIBAN3 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs375422466; called by muse, mutect2, varscan2
- NOS2 | c.1211A>G p.H404R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV58223762; called by muse, mutect2, varscan2
- PCDHGA1 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV65294825, COSV65298907; called by muse, mutect2, varscan2
- PPP1R15B | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65815793; called by muse, mutect2
- PXDN | c.4004G>C p.R1335T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV53233957; called by muse, mutect2, varscan2
- REST | c.2455G>T p.D819Y | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV58360642; called by muse, mutect2, varscan2
- SCN11A | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs770933380, COSV100181711, COSV56565857; called by muse, mutect2, varscan2
- SLC12A1 | c.1108T>G p.F370V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV57709524; called by muse, mutect2, varscan2
- SP100 | c.2274G>T p.E758D | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs371571535; called by muse, varscan2
- TBXA2R | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1389139150, COSV64343669; called by muse, mutect2, varscan2
- THOC2 | c.4762T>C p.S1588P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55545913; called by muse, mutect2, varscan2
- TMCC1 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.396); catalogued as COSV61440499; called by muse, mutect2, varscan2
- ZNF665 | c.191G>A p.R64K (on ENST00000600412; = p.R129K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV67215113; called by muse, mutect2, varscan2
- ARID1A | c.4548del p.A1517Pfs*10 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- KMT2B | c.7855_7857del p.K2619del | In Frame Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 90/543 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- VIPAS39 | c.521_522del p.R174Ifs*19 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by pindel, varscan2
- CPN1 | c.519C>T p.N173= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs1429754269, COSV64942264; called by muse, mutect2, varscan2
- EXO1 | c.348A>G p.R116= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV62217540; called by muse, mutect2, varscan2
- FAM110B | c.732G>T p.V244= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV64065152; called by muse, mutect2, varscan2
- FLI1 | c.912G>T p.G304= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV55644508; called by muse, mutect2, varscan2
- FOXN4 | c.1182G>T p.P394= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV54494099, COSV54497067; called by muse, mutect2, varscan2
- HHATL | c.1080C>T p.S360= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs756531207, COSV55134574; called by muse, mutect2, varscan2
- IGSF11 | c.504G>A p.E168= (on ENST00000393775 / NM_001015887.3; = p.E167= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV61169904; called by muse, mutect2, varscan2
- MMP20 | c.24C>T p.G8= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV52775542; called by muse, mutect2, varscan2
- P2RY8 | c.312C>T p.Y104= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1425189992, COSV67176956; called by mutect2, varscan2
- RTL9 | c.1681T>C p.L561= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as rs375611029, COSV71825604; called by muse, mutect2, varscan2
- TNC | c.4983T>G p.S1661= | Silent (SNP) | VAF 49/207 reads (24%) | catalogued as COSV60784928; called by muse, mutect2, varscan2
- MATK | chr19:3789318 T>A | 5'Flank (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
